Somatic mutation profile of tumor specimen ALCH-B1JM-TTP1-A (aliquot ALCH-B1JM-TTP1-A-2-0-D-A76C-36) from ALCHEMIST case ALCH-B1JM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 80.4 years (29,358 days).
Specimen ALCH-B1JM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c44fa71-cdf9-490a-b670-42bb5fa655eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1JM-NB1-A (Blood Derived Normal), aliquot ALCH-B1JM-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57a30864-f7f1-4c51-9eb1-d3748a87c340

The open-access MAF lists 96 somatic variants for this specimen: 65 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Nonsense Mutation 4, Intron 4, RNA 3, 3'UTR 3, Splice Region 2, Frame Shift Del 2, Splice Site 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 40/334 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BNC1 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61756499, COSV61757336; called by muse, mutect2
- BRSK1 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs201425077; called by muse, mutect2
- CTNNA3 | c.1631C>G p.A544G | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65621857; called by muse, mutect2
- CTNNA3 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 31/478 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs376250417; called by muse, mutect2
- DIPK1C | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs531235586; called by muse, mutect2
- FBXO3 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.348); catalogued as rs773191522; called by muse, mutect2, varscan2
- GSTM2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs764832394; called by muse, mutect2
- HUWE1 | c.6485G>T p.R2162L | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53351330; called by muse, mutect2, varscan2
- IGDCC3 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.058); catalogued as rs201766054, COSV60076364; called by muse, mutect2, varscan2
- KIF2B | c.520C>A p.R174S | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs769176818, COSV52126857; called by muse, mutect2
- KIF2B | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs535420177, COSV52129197; called by muse, mutect2
- KIF2B | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV52130124, COSV52135762; called by muse, mutect2
- LPA | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV100308119; called by muse, mutect2
- MAP1B | c.6824C>A p.A2275E | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as rs150487096, COSV57093328; called by muse, mutect2
- MEFV | c.2156del p.G719Afs*16 | Frame Shift Del (DEL) | VAF 30/330 reads (9%) | catalogued as COSV54827262, COSV54827972; called by mutect2, pindel
- NPAP1 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV61507173; called by muse, mutect2
- NRXN3 | c.323C>T p.T108M (on ENST00000557594 / NM_001272020.2; = p.T740M on NM_004796.6) | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs1014893545, COSV55332975; called by muse, mutect2
- PLEC | c.3287G>T p.G1096V (on ENST00000322810 / NM_201380.4; = p.G986V on NM_000445.5) | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1202092712; called by muse, mutect2
- PTK2B | c.990C>T p.A330= | Splice Region (SNP) | VAF 8/100 reads (8%) | catalogued as COSV57766157; called by muse, mutect2
- PTPRD | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 24/384 reads (6%) | catalogued as rs1189856782, COSV61993370; called by muse, mutect2
- RPE65 | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.057); catalogued as COSV52016654; called by muse, mutect2
- SCG2 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.853); catalogued as COSV59540687; called by muse, mutect2
- SEMA6A | c.922C>A p.R308S | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV57307631, COSV57312588; called by muse, mutect2
- SLFN5 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1236651334; called by muse, mutect2
- TMEM59L | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766410383; called by mutect2, varscan2
- TMEM63C | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53608283; called by muse, mutect2
- ZNF679 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99739039; called by muse, mutect2
- AMFR | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ARHGAP32 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ATP2B2 | c.1349T>C p.L450P (on ENST00000352432; = p.L416P on NM_001683.5) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPN9 | c.790-1G>C p.X264_splice | Splice Site (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- CCDC88A | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- CDK9 | c.353T>C p.L118S | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- CFAP47 | c.5348T>C p.V1783A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, mutect2
- COL24A1 | c.3245T>A p.M1082K | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.017); called by muse, mutect2
- CXCR4 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- DLGAP4 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPP7 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EYA4 | c.1921G>T p.E641* (on ENST00000531901 / NM_001301013.1; = p.E635* on NM_004100.5) | Nonsense Mutation (SNP) | VAF 20/469 reads (4%) | called by muse, mutect2
- FAM170A | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2
- FAM47B | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- GOLT1A | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2
- GRM1 | c.1782T>G p.I594M | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- HID1 | c.2122G>T p.V708L | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); called by muse, mutect2
- IGHV3-48 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 42/918 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2
- INSYN2A | c.1346C>A p.S449* | Nonsense Mutation (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- IQSEC3 | c.1557del p.A520Qfs*78 (on ENST00000538872 / NM_001170738.2; = p.A217Qfs*78 on NM_015232.1) | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- ITGA4 | c.2426T>C p.F809S | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ITPRID1 | c.741A>T p.K247N | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.231); called by muse, mutect2
- KISS1R | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KMT2A | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); called by muse, mutect2
- MALRD1 | c.4553G>T p.G1518V | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MPPE1 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); called by mutect2, varscan2
- NUP93 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2
- PAX1 | c.1462G>T p.G488* | Nonsense Mutation (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- PCK1 | c.697A>G p.S233G | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCRN3 | c.397T>G p.L133V | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC25A2 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SPINK5 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SRRM4 | c.1162G>T p.G388W | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TULP2 | c.1447+3G>T | Splice Region (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- ZNF543 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZYG11A | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP26B1 | c.867G>A p.G289= | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- FPR1 | c.492G>A p.V164= | Silent (SNP) | VAF 21/259 reads (8%) | catalogued as COSV100494216; called by muse, mutect2
- GCC1 | c.630C>T p.R210= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- GRAMD1A | c.954G>T p.P318= | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- GYS2 | c.1584C>A p.T528= | Silent (SNP) | VAF 26/502 reads (5%) | called by muse, mutect2
- ITPR2 | c.6747A>T p.P2249= | Silent (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2, varscan2
- KIR2DS4 | c.144A>G p.Q48= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs1379983442; called by muse, varscan2
- LELP1 | c.42T>A p.T14= | Silent (SNP) | VAF 24/221 reads (11%) | catalogued as COSV100907354; called by muse, mutect2, varscan2
- LRP1B | c.12831G>C p.L4277= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- LRRK1 | c.93T>A p.L31= | Silent (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- PCDHA12 | c.1527G>C p.S509= | Silent (SNP) | VAF 22/408 reads (5%) | called by muse, mutect2
- PCDHB6 | c.1395C>A p.A465= | Silent (SNP) | VAF 15/519 reads (3%) | called by muse, mutect2
- PCK1 | c.696C>A p.G232= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as COSV100100215; called by muse, mutect2
- PLPPR4 | c.2133C>T p.S711= | Silent (SNP) | VAF 30/256 reads (12%) | catalogued as COSV64565324, COSV64565634; called by muse, mutect2, varscan2
- PRKD1 | c.2364C>T p.D788= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- REG3A | c.339C>T p.T113= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs143057391; called by muse, mutect2, varscan2
- USP42 | c.1344G>A p.A448= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as rs567439071, COSV60364067; called by muse, mutect2
- ZDBF2 | c.546G>T p.V182= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- ZNF142 | c.3906T>G p.A1302= (on ENST00000411696 / NM_001379660.1; = p.A1102= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 16/313 reads (5%) | called by muse, mutect2
- CACNG8 | c.*5G>A | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- FOXP2 | c.*870C>T | 3'UTR (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- IGKV1-13 | n.270G>T | RNA (SNP) | VAF 26/712 reads (4%) | called by muse, mutect2
- MIR663B | n.63G>C | RNA (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1588C>T | RNA (SNP) | VAF 23/250 reads (9%) | called by muse, mutect2
- PDLIM2 | chr8:22594580 G>A | 3'Flank (SNP) | VAF 30/242 reads (12%) | called by muse, mutect2, varscan2
- SNX5 | c.-207G>T | 5'UTR (SNP) | VAF 10/117 reads (9%) | catalogued as rs1001632730; called by muse, mutect2
- SPG7 | c.377-89C>G | Intron (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
- ST7 | c.151+2896T>C | Intron (SNP) | VAF 26/378 reads (7%) | called by muse, mutect2
- TRPM1 | c.899+18C>G | Intron (SNP) | VAF 20/261 reads (8%) | called by muse, mutect2
- VWF | c.55+20C>A | Intron (SNP) | VAF 32/257 reads (12%) | catalogued as rs1283796226; called by muse, mutect2, varscan2
- ZNF99 | c.*2992C>T | 3'UTR (SNP) | VAF 10/205 reads (5%) | called by muse, mutect2
